Somatic mutation profile of tumor specimen TCGA-85-8664-01A (aliquot TCGA-85-8664-01A-11D-2395-08) from TCGA case TCGA-85-8664, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.8 years (26,954 days).
Specimen TCGA-85-8664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d8cb28a-292a-452b-8fca-af08332be60a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8664-10A (Blood Derived Normal), aliquot TCGA-85-8664-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cea270ba-b27e-46e5-b6bf-1bb02e0c1cbf

The open-access MAF lists 235 somatic variants for this specimen: 181 protein-altering or splice-affecting, 50 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 50, Nonsense Mutation 11, Frame Shift Del 10, Splice Site 2, In Frame Ins 1, In Frame Del 1, Intron 1, 5'UTR 1, 5'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 53/63 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.2621C>G p.T874S | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99536865; called by muse, mutect2, varscan2
- AFF2 | c.1583G>A p.W528* | Nonsense Mutation (SNP) | VAF 74/104 reads (71%) | catalogued as COSV99661258; called by muse, mutect2, varscan2
- ALDH2 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99922633; called by muse, mutect2, varscan2
- AQP8 | c.24T>G p.C8W | Missense Mutation (SNP) | VAF 145/221 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV99563623; called by muse, mutect2, varscan2
- ARMC8 | c.722T>C p.V241A (on ENST00000469044 / NM_001363941.2; = p.V227A on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1329760874, COSV100627452; called by muse, mutect2, varscan2
- C19orf12 | c.194-1G>T p.X65_splice (on ENST00000392278 / NM_001031726.3; = p.X54_splice on NM_031448.6) | Splice Site (SNP) | VAF 44/132 reads (33%) | catalogued as COSV100080404, COSV60364422; called by muse, mutect2, varscan2
- CACNA2D4 | c.2085C>G p.D695E | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1477105980, COSV99764894; called by muse, mutect2, varscan2
- CCHCR1 | c.2154C>G p.S718R | Missense Mutation (SNP) | VAF 231/312 reads (74%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV99455860; called by muse, mutect2, varscan2
- CDC42BPG | c.1487G>T p.R496L | Missense Mutation (SNP) | VAF 148/212 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs768977915, COSV100711912, COSV61348348; called by muse, mutect2, varscan2
- CEP131 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV99487716; called by muse, mutect2, varscan2
- CHAT | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV100339515; called by muse, mutect2, varscan2
- CHL1 | c.772T>A p.L258M (on ENST00000397491 / NM_001253387.1; = p.L274M on NM_006614.4) | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769233255, COSV99849699; called by muse, mutect2, varscan2
- CMYA5 | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1217239264, COSV101483714; called by muse, mutect2
- CNTNAP2 | c.3016G>C p.G1006R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100661636; called by muse, mutect2, varscan2
- COA8 | c.263A>C p.Q88P | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV99914568; called by muse, mutect2, varscan2
- CPB2 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV99472883; called by muse, mutect2, varscan2
- CRAMP1 | c.3620C>T p.S1207F | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51963945, COSV99245480; called by muse, mutect2, varscan2
- CRIM1 | c.1381A>T p.I461F | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99752073; called by muse, mutect2, varscan2
- CSMD3 | c.2249C>A p.T750K (on ENST00000297405 / NM_001363185.1; = p.T646K on NM_052900.3) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.837); catalogued as COSV52337134, COSV99820895; called by muse, mutect2, varscan2
- CTBS | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV99759572; called by muse, mutect2
- CTSW | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV100327167; called by muse, mutect2, varscan2
- CYP3A4 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100315343; called by muse, mutect2, varscan2
- DACH2 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100912297; called by muse, mutect2, varscan2
- DCBLD2 | c.807G>C p.L269F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100471192; called by muse, mutect2, varscan2
- DCHS1 | c.9623T>C p.V3208A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100197108; called by muse, mutect2, varscan2
- DMRTA1 | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1050428620, COSV100364596; called by muse, mutect2, varscan2
- DNAH8 | c.2918A>C p.Y973S | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs764580800, COSV100542701; called by muse, mutect2, varscan2
- DNMBP | c.4060G>T p.D1354Y | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100142841, COSV60621241; called by muse, mutect2, varscan2
- DOCK3 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV99808350; called by muse, mutect2, varscan2
- DPP6 | c.2570C>T p.T857I (on ENST00000377770 / NM_001364500.2; = p.T795I on NM_001936.5) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100122444; called by muse, varscan2
- DUS2 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100732350; called by muse, mutect2, varscan2
- ECRG4 | c.248G>C p.W83S | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99430177; called by muse, mutect2, varscan2
- EFHB | c.200G>C p.S67T | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99858992; called by muse, mutect2, varscan2
- EPG5 | c.6697A>C p.I2233L | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99956229; called by muse, mutect2, varscan2
- F13A1 | c.1770C>G p.I590M | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.671); catalogued as COSV99341873; called by muse, mutect2
- F13B | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.835); catalogued as COSV100803139, COSV66375912; called by muse, mutect2, varscan2
- F13B | c.1420G>T p.G474W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100803140; called by muse, mutect2, varscan2
- FAAH2 | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0.066); catalogued as COSV100887089; called by muse, mutect2, varscan2
- FAF1 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1375328443, COSV100875148, COSV65644787; called by muse, mutect2, varscan2
- FAM135B | c.3793T>A p.L1265I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52706554, COSV99417277; called by muse, mutect2, varscan2
- FAM155B | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1188126249, COSV52937003; called by muse, mutect2, varscan2
- FBXL7 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1219818114, COSV61641181; called by mutect2, varscan2
- FBXO7 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99832355; called by muse, mutect2, varscan2
- FLG | c.8953T>A p.S2985T | Missense Mutation (SNP) | VAF 69/389 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); catalogued as COSV64251985; called by muse, mutect2, varscan2
- FOXN2 | c.83A>T p.Y28F | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.107); catalogued as COSV100488903; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as rs749090310, COSV100435172; called by mutect2, varscan2
- GIMAP2 | c.291G>C p.R97S | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.33); PolyPhen benign (0.121); catalogued as COSV99785167; called by muse, mutect2, varscan2
- GNA12 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV99282213; called by muse, mutect2, varscan2
- GPR65 | c.695C>G p.T232R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV99965913; called by muse, mutect2, varscan2
- GRAMD1B | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100454179; called by muse, mutect2, varscan2
- GREB1 | c.2770A>T p.T924S | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.224); catalogued as COSV99301997; called by muse, mutect2, varscan2
- GUCY1A1 | c.1462G>T p.V488F | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376624635, COSV56653848; called by muse, mutect2, varscan2
- HECTD1 | c.1673C>G p.A558G | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV101237286; called by muse, mutect2, varscan2
- HEPHL1 | c.2336G>C p.G779A | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243349; called by muse, mutect2, varscan2
- HERPUD2 | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100257751, COSV60945338; called by muse, mutect2, varscan2
- HIVEP2 | c.6455A>G p.H2152R | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.229); catalogued as COSV99171403; called by muse, mutect2, varscan2
- HPCAL1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100323680; called by muse, mutect2, varscan2
- HSPA12A | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100979695; called by muse, mutect2, varscan2
- IL1B | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641631; called by muse, mutect2, varscan2
- IL7R | c.455C>G p.T152R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100285735; called by muse, mutect2, varscan2
- IRAK1BP1 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100884824; called by muse, mutect2
- IRF2BP1 | c.748C>G p.H250D | Missense Mutation (SNP) | VAF 97/175 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100138771; called by muse, mutect2, varscan2
- ITGB4 | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99563138; called by muse, mutect2, varscan2
- JSRP1 | c.838C>A p.R280S | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1431673559, COSV99677518; called by muse, mutect2, varscan2
- KANK2 | c.1328G>C p.S443T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100762967; called by muse, mutect2, varscan2
- KIF24 | c.95T>C p.L32S | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100799070; called by muse, mutect2, varscan2
- KIF2B | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV52135491, COSV99274447; called by muse, mutect2, varscan2
- KIF2B | c.1987C>G p.L663V | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99274449; called by muse, mutect2, varscan2
- LEP | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV100451325; called by muse, mutect2, varscan2
- LRRIQ1 | c.775T>A p.L259I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs774170751, COSV101279229; called by muse, mutect2, varscan2
- LRRTM1 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV99701570; called by muse, mutect2, varscan2
- MAP7D2 | c.430A>C p.K144Q | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101107084; called by muse, mutect2, varscan2
- MAPK4 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs895465186, COSV101244975; called by muse, mutect2, varscan2
- MDN1 | c.3251G>A p.G1084E | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101020656; called by muse, mutect2, varscan2
- MKX | c.821A>T p.N274I | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV101008466; called by muse, mutect2, varscan2
- MOB1B | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV100511391; called by muse, mutect2, varscan2
- MSH4 | c.1987A>C p.I663L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99590320; called by muse, mutect2, varscan2
- MTMR11 | c.983del p.P328Lfs*5 (on ENST00000439741 / NM_001145862.2; = p.P256Lfs*5 on NM_181873.3) | Frame Shift Del (DEL) | VAF 32/174 reads (18%) | catalogued as COSV63807705; called by mutect2, pindel, varscan2
- MTOR | c.7093G>T p.A2365S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100815602; called by muse, mutect2, varscan2
- MUTYH | c.48G>T p.R16S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV100587862; called by muse, mutect2, varscan2
- MUTYH | c.47G>T p.R16M | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV100587864; called by muse, mutect2, varscan2
- MXRA5 | c.6662G>A p.C2221Y | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475382; called by muse, mutect2, varscan2
- NALCN | c.25A>T p.R9W | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV51923524, COSV99212653; called by muse, mutect2, varscan2
- NAV3 | c.2779G>T p.D927Y | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99885852; called by muse, mutect2, varscan2
- NDUFV1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.837); catalogued as CM138572, COSV100295209; called by muse, mutect2, varscan2
- NEFH | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100151150, COSV60217522; called by muse, mutect2, varscan2
- NETO1 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV100198021, COSV55000873; called by muse, mutect2, varscan2
- NKX3-1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.335); catalogued as COSV101082692; called by muse, mutect2, varscan2
- NRG3 | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100930337, COSV64578791; called by muse, mutect2, varscan2
- OR10G8 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV101461765; called by muse, mutect2, varscan2
- OR10Q1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 59/113 reads (52%) | catalogued as COSV100372100, COSV100372383; called by muse, mutect2, varscan2
- OR2M3 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV71758943, COSV71758971; called by muse, mutect2, varscan2
- OR4D10 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV101596989; called by muse, mutect2
- OR6B3 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100096771; called by muse, mutect2, varscan2
- OR6C6 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV100626390; called by muse, mutect2, varscan2
- OR6T1 | c.304T>A p.Y102N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100189650; called by muse, varscan2
- OR8I2 | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 48/99 reads (48%) | catalogued as rs141691557, COSV100135786; called by muse, mutect2, varscan2
- OTULIN | c.230-1G>C p.X77_splice | Splice Site (SNP) | VAF 20/38 reads (53%) | catalogued as COSV99419477; called by muse, mutect2, varscan2
- PCF11 | c.3195G>T p.R1065S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.073); catalogued as COSV100017647; called by muse, mutect2, varscan2
- PEAK1 | c.1667G>C p.G556A | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV100432258, COSV56938826; called by muse, mutect2, varscan2
- PITPNC1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV100082662; called by muse, mutect2, varscan2
- PKHD1 | c.10907A>T p.Q3636L | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1295672080, COSV100943160; called by muse, mutect2, varscan2
- PLCH1 | c.1486G>T p.E496* (on ENST00000340059 / NM_001130960.2; = p.E508* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/60 reads (58%) | catalogued as COSV100395327; called by muse, mutect2, varscan2
- PLXNA4 | c.2920A>G p.I974V | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as rs1337294647, COSV100321844; called by muse, mutect2, varscan2
- PNCK | c.107G>T p.G36V (on ENST00000340888 / NM_001366975.1; = p.G119V on NM_001039582.3) | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT tolerated (0.37); PolyPhen benign (0.255); catalogued as COSV100562112; called by muse, mutect2, varscan2
- POTEF | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as COSV100664459; called by muse, mutect2, varscan2
- PPP1R9A | c.1244G>C p.G415A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99194488; called by muse, mutect2, varscan2
- PPP6R1 | c.2426A>G p.H809R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100497545; called by muse, mutect2, varscan2
- PRKD1 | c.2683C>G p.P895A | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.03); catalogued as COSV100118981; called by muse, mutect2, varscan2
- PSMA1 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.7); catalogued as COSV101123605; called by muse, mutect2, varscan2
- PSMD12 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1263664869, COSV62065726; called by muse, mutect2, varscan2
- PTPRE | c.1763G>T p.R588L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99616615; called by muse, mutect2, varscan2
- PTPRH | c.162T>A p.D54E | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1294140798, COSV99670578; called by muse, mutect2, varscan2
- PUM2 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100162991; called by muse, mutect2, varscan2
- RAD51D | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as rs374357106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALA | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV50049618, COSV99143311; called by muse, mutect2, varscan2
- RANBP6 | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99423873; called by muse, mutect2, varscan2
- RAPGEF6 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 28/46 reads (61%) | catalogued as COSV99724840; called by muse, mutect2, varscan2
- RGS22 | c.514A>T p.K172* | Nonsense Mutation (SNP) | VAF 36/73 reads (49%) | catalogued as COSV100692926; called by muse, mutect2, varscan2
- RIMBP2 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99897974; called by muse, mutect2, varscan2
- RNF130 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99992429; called by muse, mutect2, varscan2
- RNGTT | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99665263; called by muse, mutect2
- RPL39L | c.111C>G p.Y37* | Nonsense Mutation (SNP) | VAF 49/255 reads (19%) | catalogued as COSV99961487; called by muse, mutect2, varscan2
- RPTN | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 111/312 reads (36%) | catalogued as COSV60168346; called by muse, mutect2, varscan2
- RYR1 | c.6298C>A p.H2100N | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100614078, COSV62090398; called by muse, mutect2, varscan2
- RYR2 | c.11795A>T p.Q3932L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100767158; called by muse, mutect2, varscan2
- SCAF11 | c.2936G>T p.R979L | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65478955; called by muse, mutect2, varscan2
- SEMA5A | c.2200A>C p.K734Q | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV101226750; called by muse, mutect2
- SFTPA1 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100956856; called by muse, mutect2, varscan2
- SH3TC1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs552621094, COSV55284475; called by muse, mutect2, varscan2
- SHROOM3 | c.5101G>T p.G1701C | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933275; called by muse, mutect2, varscan2
- SLC12A5 | c.2023G>A p.A675T (on ENST00000454036 / NM_001134771.2; = p.A652T on NM_020708.5) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV99715090; called by muse, mutect2
- SLC6A2 | c.1815C>A p.D605E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99573140; called by muse, mutect2, varscan2
- SLFN13 | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99539627; called by muse, mutect2, varscan2
- SORCS1 | c.3299G>T p.G1100V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV99542140; called by muse, mutect2, varscan2
- SP1 | c.2182A>T p.S728C (on ENST00000327443 / NM_138473.3; = p.S721C on NM_003109.1) | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100540349; called by muse, mutect2, varscan2
- SRRT | c.2263A>G p.T755A | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.181); catalogued as COSV99573633; called by muse, mutect2, varscan2
- SUPT5H | c.1776C>A p.N592K | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100781878; called by muse, mutect2, varscan2
- TAS2R60 | c.272del p.P91Lfs*6 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | catalogued as COSV100223542; called by mutect2, pindel, varscan2
- TECPR1 | c.1482G>T p.E494D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as COSV101130190; called by muse, mutect2, varscan2
- TGIF2LX | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV52214933, COSV99383247; called by muse, mutect2, varscan2
- TMED5 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV100939104; called by muse, mutect2, varscan2
- TMEM132B | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as rs957060469, COSV100168074; called by muse, mutect2, varscan2
- TMEM144 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56703319, COSV99646563; called by muse, mutect2, varscan2
- TRAF2 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 47/62 reads (76%) | catalogued as COSV56038207, COSV99916118; called by muse, mutect2, varscan2
- TRPM1 | c.2028C>A p.F676L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV56631656, COSV99855141; called by muse, mutect2, varscan2
- TTC39C | c.1724C>T p.A575V (on ENST00000317571 / NM_001135993.2; = p.A514V on NM_153211.4) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV100455049; called by muse, mutect2, varscan2
- UNC79 | c.1169C>T p.A390V (on ENST00000393151 / NM_001346218.2; = p.A213V on NM_020818.5) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.915); catalogued as COSV99825220; called by muse, mutect2, varscan2
- USP24 | c.617A>G p.N206S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as rs1225661474, COSV99598591; called by muse, mutect2, varscan2
- UTRN | c.3903del p.I1302Sfs*5 | Frame Shift Del (DEL) | VAF 25/123 reads (20%) | catalogued as rs1188385573; called by mutect2, pindel, varscan2
- VDR | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV99968488, COSV99968849; called by muse, mutect2, varscan2
- XRN1 | c.4724C>T p.P1575L | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as COSV99377002; called by muse, mutect2, varscan2
- ZFHX4 | c.2358G>T p.M786I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99254471; called by muse, mutect2, varscan2
- ZNF101 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100543440; called by mutect2, varscan2
- ZNF217 | c.1065C>A p.H355Q | Missense Mutation (SNP) | VAF 129/188 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100184094; called by muse, mutect2, varscan2
- ZNF425 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1477895744, COSV100955347, COSV100955432; called by muse, mutect2, varscan2
- ZNF526 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 139/189 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99725010; called by muse, mutect2, varscan2
- ZNF804A | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); catalogued as rs368984918, COSV56476823; called by muse, mutect2, varscan2
- ZNF813 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV101124653; called by muse, mutect2, varscan2
- ZNF839 | c.1429A>G p.S477G (on ENST00000558850 / NM_001267827.1; = p.S593G on NM_018335.5) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99215968; called by muse, mutect2, varscan2
- ZPR1 | c.886A>T p.N296Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99911110; called by muse, mutect2, varscan2
- ZWINT | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.297); catalogued as COSV100571461; called by muse, mutect2, varscan2
- ADAMTS6 | c.1890G>A p.M630I | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.9586_9594del p.S3196_A3198del | In Frame Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.3460del p.V1154Sfs*25 (on ENST00000651564; = p.V1107Sfs*25 on NM_015692.5) | Frame Shift Del (DEL) | VAF 39/117 reads (33%) | called by mutect2, pindel, varscan2
- ETV6 | c.1081del p.E361Rfs*10 | Frame Shift Del (DEL) | VAF 37/142 reads (26%) | called by mutect2, pindel, varscan2
- FLNC | c.5858G>C p.R1953T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- FRMPD2 | c.3302G>T p.C1101F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- GOLGA6B | c.1882del p.Q628Rfs*29 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | called by mutect2, varscan2
- IGHA1 | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGKV1-9 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- IGLV2-33 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 82/182 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LAMA2 | c.6109del p.V2037Lfs*29 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- NAALADL2 | c.2106_2116del p.I703Dfs*4 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel
- PLA2G4C | c.1553_1562del p.I518Sfs*2 | Frame Shift Del (DEL) | VAF 8/98 reads (8%) | called by mutect2, pindel
- PRAMEF17 | c.1369T>A p.C457S | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1018G>C p.A340P | Missense Mutation (SNP) | VAF 104/136 reads (76%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- WDR20 | c.137_146del p.N46Tfs*5 | Frame Shift Del (DEL) | VAF 34/87 reads (39%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.891_896dup p.S298_C299insWS | In Frame Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- ZNF320 | c.688dup p.A230Gfs*8 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.6594T>A p.T2198= | Silent (SNP) | VAF 54/67 reads (81%) | catalogued as COSV99794048; called by muse, mutect2, varscan2
- ANKAR | c.2712T>A p.A904= | Silent (SNP) | VAF 32/48 reads (67%) | catalogued as COSV99853768; called by muse, mutect2, varscan2
- ARHGAP31 | c.1951C>T p.L651= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as COSV99956412; called by muse, mutect2, varscan2
- ARHGEF10 | c.2148G>C p.T716= (on ENST00000398564; = p.T691= on NM_014629.4) | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as rs148136629, COSV100033413; called by muse, mutect2, varscan2
- ARMC4 | c.1945C>T p.L649= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as rs12261771, COSV100536112; called by muse, mutect2, varscan2
- C2orf78 | c.1365G>A p.P455= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs763384336, COSV68516321, COSV68516677; called by mutect2, varscan2
- CABIN1 | c.4320G>A p.L1440= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99572480; called by muse, mutect2, varscan2
- CHST3 | c.72C>T p.Y24= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs542040061, COSV100910362, COSV64151224; called by muse, mutect2, varscan2
- DSCAML1 | c.2316G>A p.S772= (on ENST00000321322; = p.S712= on NM_020693.4) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs570510844, COSV58395280; called by muse, mutect2, varscan2
- EPHA10 | c.240G>T p.L80= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as COSV100139655; called by muse, mutect2, varscan2
- ERICH3 | c.4131C>A p.S1377= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV100443095, COSV58601260, COSV58608475; called by muse, mutect2, varscan2
- FAM135B | c.3015A>T p.A1005= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV99417283; called by muse, mutect2, varscan2
- FUT9 | c.1023G>T p.V341= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100132816, COSV100133391, COSV56153608; called by mutect2, varscan2
- GNAS | c.810G>A p.A270= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as rs1290398674, COSV100007136, COSV58332640; called by muse, mutect2, varscan2
- IGLJ7 | c.45C>A p.L15= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- IGSF1 | c.2049C>T p.L683= | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as COSV100811753; called by muse, mutect2, varscan2
- ITGBL1 | c.1407T>C p.C469= | Silent (SNP) | VAF 69/100 reads (69%) | catalogued as COSV101084034; called by muse, mutect2, varscan2
- LRRTM4 | c.469C>A p.R157= | Silent (SNP) | VAF 42/68 reads (62%) | catalogued as COSV101297404, COSV69139923; called by muse, mutect2, varscan2
- LYZ | c.84A>G p.R28= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as COSV99719984; called by muse, mutect2, varscan2
- MAL | c.282C>T p.T94= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs761322906, COSV100015595; called by muse, mutect2, varscan2
- MBTPS1 | c.123G>C p.L41= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100597259; called by muse, mutect2, varscan2
- MC5R | c.54G>A p.E18= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs761305888, COSV100228876, COSV100229135; called by muse, mutect2, varscan2
- MEIS2 | c.45C>T p.D15= (on ENST00000561208 / NM_170675.5; = p.D2= on NM_002399.3) | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as rs750782482, COSV99575561; called by muse, mutect2, varscan2
- MRC1 | c.813T>C p.S271= | Silent (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- MYO1A | c.1188G>C p.V396= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV100270433; called by muse, mutect2, varscan2
- NOS1 | c.1707C>T p.L569= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV100499846, COSV100500865; called by muse, varscan2
- OR4A16 | c.162C>T p.G54= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV100124945; called by muse, mutect2, varscan2
- OR5H14 | c.792C>A p.S264= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101454042; called by muse, varscan2
- PAPPA2 | c.4710C>A p.V1570= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100867403; called by muse, mutect2, varscan2
- PDPR | c.2532C>A p.I844= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV55351583, COSV99847582; called by muse, mutect2, varscan2
- PLXNA3 | c.2904G>A p.V968= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100859777; called by muse, mutect2, varscan2
- POTEF | c.1980G>T p.L660= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV100664461; called by muse, mutect2, varscan2
- PPP2R3B | c.1464G>T p.L488= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV101180630; called by muse, mutect2, varscan2
- PRKCB | c.1174C>A p.R392= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV100331765, COSV100332253; called by muse, mutect2, varscan2
- PSD3 | c.2130G>T p.L710= (on ENST00000440756; = p.L709= on NM_015310.4) | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV99675034; called by muse, mutect2, varscan2
- PTPN22 | c.954T>A p.T318= (on ENST00000359785 / NM_001193431.2; = p.T263= on NM_012411.5) | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV100703323; called by muse, mutect2, varscan2
- RFFL | c.309G>A p.K103= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV99265105; called by muse, mutect2, varscan2
- ROCK2 | c.3216T>G p.S1072= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100253701; called by muse, mutect2, varscan2
- SAMD9L | c.4374C>A p.S1458= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as rs201797999, COSV100560185; called by muse, mutect2, varscan2
- SIGLEC10 | c.1257C>T p.H419= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs376171817, COSV59485702; called by muse, mutect2, varscan2
- SLC43A3 | c.1104G>T p.S368= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs750231881, COSV100725138, COSV100725285; called by muse, varscan2
- SLC6A2 | c.714G>A p.L238= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99573139; called by muse, mutect2, varscan2
- SPG11 | c.4644G>T p.P1548= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs1021717728, COSV99967840; called by muse, mutect2, varscan2
- TCHH | c.328T>C p.L110= | Silent (SNP) | VAF 91/275 reads (33%) | catalogued as COSV100914846; called by muse, mutect2, varscan2
- TIAM2 | c.3183C>A p.I1061= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV99264899; called by muse, mutect2, varscan2
- TMEM132D | c.1632C>A p.P544= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV101242509; called by muse, mutect2, varscan2
- TOM1 | c.177G>T p.V59= | Silent (SNP) | VAF 36/53 reads (68%) | catalogued as COSV101146394; called by muse, mutect2, varscan2
- TSEN2 | c.1191G>A p.R397= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as COSV99538705; called by muse, mutect2, varscan2
- UBE4B | c.165C>G p.L55= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99475454; called by muse, mutect2, varscan2
- ZCCHC13 | c.498G>A p.Q166= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100272440; called by muse, mutect2
- OSGIN1 | n.1350dup | RNA (INS) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.-7C>T | 5'UTR (SNP) | VAF 53/77 reads (69%) | catalogued as COSV99394555; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791082 T>A | 5'Flank (SNP) | VAF 52/153 reads (34%) | called by muse, mutect2, varscan2
- TBRG4 | c.412-292A>G | Intron (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99345212; called by muse, mutect2, varscan2
